Surgical pathology report (de-identified scan), TCGA case TCGA-21-1072, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1072-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

A: PORTION OF 6TH RIB

B: L9 NODES

C: LEVEL 7 NODES

D: LYMPH NODE ON INFERIOR PULMONARY VEIN

E: LT LUNG

F: LEVEL 5 NODES

GROSS DESCRIPTION: The specimen is received in six parts.

SOURCE OF TISSUE: 1. Labeled #1 "portion of 6th rib"

GROSS DESCRIPTION: The specimen consists of a portion of rib measuring 1.4 cm in length with an average diameter of 0.7 cm. There is a scant amount of soft tissue attached to the specimen. A representative section is submitted in one block following decalcification.

DESIGNATION OF SECTIONS: Block 1.

SUMMARY OF SECTIONS: Undesignated - 1.

SOURCE OF TISSUE: 2. Labeled #2 "left level 9 node"

GROSS DESCRIPTION: The specimen consists of a yellow-tan portion of soft tissue measuring 0.6 x 0.5 x 0.3 cm. The specimen contains a focal area of anthracotic pigmentation. The specimen is submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 2.

SUMMARY OF SECTIONS: Undesignated - 1.

SOURCE OF TISSUE: 3. Labeled #3 "level 7 lymph node"

GROSS DESCRIPTION: The specimen consists of two fragments of gray-black soft tissue with anthracotic pigmentation measuring 1.3 x 0.9 x 0.4 cm. The specimen is submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 3.

SUMMARY OF SECTIONS: Undesignated - 3.

[page 2 of 3]
SOURCE OF TISSUE: 4. Labeled #4 "lymph node in inferior pulmonary vein"

GROSS DESCRIPTION: The specimen consists of a gray-tan anthracotic stained soft tissue measuring 1.3 x 0.6 x 0.5 cm. The specimen is submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 4.

SUMMARY OF SECTIONS: Undesignated - 1.

SOURCE OF TISSUE: 5. Labeled #5 "left lung"

FROZEN SECTION DIAGNOSIS: 5FS - BRONCHIAL MARGIN NEGATIVE FOR TUMOR

GROSS DESCRIPTION: The specimen was received fresh for frozen section. The specimen consists of a left pneumonectomy measuring 22.0 x 14.5 x 3.0 cm. The specimen contains a bronchus measuring 4.0 cm in length with a diameter of 2.0 cm. The pleura is pink-tan with diffuse areas of anthracotic pigmentation. There are no areas of puckering or induration identified grossly on the pleura. The bronchial tree was dissected to reveal the upper bronchus containing a pink-tan soft mass which obliterates the bronchiole. The mass measures 2.4 x 2.5 cm in greatest dimension. The surrounding lung parenchyma contains mucous plugs. The surrounding vasculature is not involved with the tumor. The bronchial margin was frozen and the frozen section residue is submitted in one block. Representative sections are submitted in eight blocks.

DESIGNATION OF SECTIONS: 5FS, 5A-5G

SUMMARY OF SECTIONS: 5FS frozen section residue, 5A vascular margin, 5B four lymph nodes, 5C four lymph nodes, 5D-5E bronchus with tumor, 5F the parenchyma nearest to the tumor and 5G normal lung.

SOURCE OF TISSUE: 6. Labeled #6 "level 5 lymph node"

GROSS DESCRIPTION: The specimen consists of a gray-black anthracotic stained soft tissue measuring 1.2 x 0.9 x 0.5 cm. The specimen is bisected and submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 6.

SUMMARY OF SECTIONS: Undesignated - 2.

[page 3 of 3]
Final Diagnosis:

DIAGNOSIS:

1. PORTION OF 6TH RIB:

- NO TUMOR SEEN.

2. L9 LYMPH NODE:

- NO TUMOR SEEN (0/1).

3. LEVEL 7 LYMPH NODE:

- NO TUMOR SEEN (0/2).

4. LYMPH NODE IN INFERIOR PULMONARY VEIN:

- NO TUMOR SEEN (0/1).

5. LEFT LUNG (PNEUMONECTOMY):

- KERATINIZING SQUAMOUS CELL CARCINOMA GRADE II (2.5 CM).
- PLEURA, BRONCHIAL AND VASCULAR MARGINS NEGATIVE FOR TUMOR.
- NEGATIVE PERIBRONCHIAL LYMPH NODES (0/9) (PT2N0) (INVOLVEMENT OF THE
LEFT MAIN BRONCHUS).
- NON-NEOPLASTIC LUNG REVEALS ATELECTASIS.

6. LEVEL 5 LYMPH NODE:

- NO TUMOR SEEN (0/1).

Source: NCI Genomic Data Commons file 4d972628-d707-4e60-a9aa-2ff8c4637bdd (TCGA-21-1072.F035B8F2-1C3E-49B4-8FF5-101AF46DB322.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).